TCGA case TCGA-06-0881 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b6c184a-5868-4a51-8a82-aa16a7e65126

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 504 days (1.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,278 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 58 days; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 133 days; Number of cycles: 2; Treatment dose: 140 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 150 days; Number of cycles: 2; Treatment dose: 748 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Adjuvant; Days to treatment start: 150 days; Number of cycles: 2; Treatment dose: 250 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Initial disease status: Progressive Disease; Days to treatment start: 229 days; Days to treatment end: 394 days (1.1 years); Treatment dose: 3,000 cGy; Course number: 2; Number of fractions: 5; Treatment anatomic sites: Locoregional Site.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 50.4 years (18,419 days); Days to diagnosis: 141 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 141 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 141 days.
- Days to follow up: 178 days; Disease response: With Tumor.
- Days to follow up: 504 days (1.4 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- Karnofsky performance status: 100; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.1; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-06-0881-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 0.
  Slide TCGA-06-0881-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 0.
- Sample TCGA-06-0881-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0881-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Radiation treatment 2: Radiation type other: Fractionated stereotactic radiosurgert; Therapy regimen: Progression.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 504 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 504 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 141 days.
